Somatic mutation profile of cancer-model specimen HCM-BROD-0194-C15-85B (3D Organoid, passage 4; aliquot HCM-BROD-0194-C15-85B-01D-A79C-36), derived from the primary tumor of HCMI case HCM-BROD-0194-C15, project HCMI-CMDC (NCI Cancer Model Development for the Human Cancer Model Initiative). Sex at birth: male; Vital status: Dead; Primary diagnosis: Adenocarcinoma, NOS; Tissue or organ of origin: Esophagus, NOS; AJCC pathologic stage: Stage IV; Age at diagnosis: 47.8 years (17,477 days).
Specimen HCM-BROD-0194-C15-85B: Sample type: Next Generation Cancer Model; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: 3D Organoid; Preservation method: Frozen; Passage count: 4.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 3beccb05-223e-4d68-8a42-3e986a371beb.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen HCM-BROD-0194-C15-10B (Blood Derived Normal), aliquot HCM-BROD-0194-C15-10B-01D-A79C-36; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/2bee5118-0a5a-4094-a750-c28d2c8ddfa6

The open-access MAF lists 135 somatic variants for this specimen: 88 protein-altering or splice-affecting, 39 silent, 8 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 77, Silent 39, 3'UTR 3, Nonsense Mutation 3, Frame Shift Ins 2, Intron 2, Frame Shift Del 2, Splice Region 1, Splice Site 1, Translation Start Site 1, RNA 1, 5'Flank 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- CDKN2A | c.44G>A p.W15* | Nonsense Mutation (SNP) | VAF 826/831 reads (99%) | catalogued as rs876658556, CM960269, COSV58683138, COSV58721704; ClinVar: pathogenic; called by muse, mutect2, varscan2
- TP53 | c.398T>A p.M133K | Missense Mutation (SNP) | VAF 256/256 reads (100%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen benign (0.061); catalogued as CM910373, CM973400, COSV52744834, COSV52795528, COSV52821486, COSV52852024; called by muse, mutect2, varscan2
- ACAP1 | c.230C>T p.A77V | Missense Mutation (SNP) | VAF 21/294 reads (7%) | SIFT tolerated (0.24); PolyPhen benign (0.015); catalogued as rs541681609, COSV50134698; called by muse, mutect2
- ADAMTS12 | c.1391A>C p.K464T | Missense Mutation (SNP) | VAF 24/404 reads (6%) | SIFT deleterious (0.02); PolyPhen benign (0.011); catalogued as rs780506138, COSV61255039, COSV61262098; called by muse, mutect2
- ASB17 | c.130G>A p.E44K | Missense Mutation (SNP) | VAF 51/350 reads (15%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (0.981); catalogued as rs1389873604, COSV99407755, COSV99407871, COSV99407958; called by muse, mutect2, varscan2
- ASTN1 | c.3439G>A p.V1147M | Missense Mutation (SNP) | VAF 42/355 reads (12%) | SIFT tolerated (0.21); PolyPhen possibly damaging (0.584); catalogued as rs151279922; called by muse, mutect2, varscan2
- AVPR1A | c.850C>T p.R284W | Missense Mutation (SNP) | VAF 300/458 reads (66%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs767540299; called by muse, varscan2
- BAHCC1 | c.497G>A p.R166H | Missense Mutation (SNP) | VAF 217/498 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs782753355; called by muse, mutect2, varscan2
- BEND4 | c.264dup p.G89Rfs*65 | Frame Shift Ins (INS) | VAF 128/388 reads (33%) | catalogued as rs1246615541; called by mutect2, varscan2
- BRIP1 | c.512G>T p.R171I | Missense Mutation (SNP) | VAF 130/282 reads (46%) | SIFT deleterious (0); PolyPhen probably damaging (0.921); catalogued as COSV99370435; called by muse, mutect2, varscan2
- CHIA | c.1152G>T p.K384N (on ENST00000343320; = p.K276N on NM_021797.4 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 38/440 reads (9%) | SIFT tolerated (0.05); PolyPhen benign (0.223); catalogued as COSV58477792; called by muse, mutect2
- CLASP2 | c.1246C>T p.L416F | Missense Mutation (SNP) | VAF 162/201 reads (81%) | SIFT deleterious (0.02); PolyPhen benign (0.34); catalogued as rs963434755; called by muse, mutect2, varscan2
- CSF2RB | c.674G>A p.R225H | Missense Mutation (SNP) | VAF 36/506 reads (7%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.868); catalogued as rs753738312; called by muse, mutect2
- CYLC1 | c.251T>G p.I84S | Missense Mutation (SNP) | VAF 12/308 reads (4%) | SIFT tolerated (0.44); PolyPhen benign (0.009); catalogued as rs1358418612, COSV61415383; called by muse, mutect2
- DPP6 | c.266C>T p.P89L (on ENST00000377770 / NM_001364500.2; = p.P27L on NM_001936.5) | Missense Mutation (SNP) | VAF 214/244 reads (88%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs567844586; called by muse, mutect2, varscan2
- DRAXIN | c.143C>T p.A48V | Missense Mutation (SNP) | VAF 52/674 reads (8%) | SIFT tolerated (0.07); PolyPhen benign (0.232); catalogued as rs1001837034; called by muse, mutect2
- EFS | c.311C>T p.P104L | Missense Mutation (SNP) | VAF 173/384 reads (45%) | SIFT deleterious (0); PolyPhen possibly damaging (0.886); catalogued as rs780112461, COSV53731809; called by muse, mutect2, varscan2
- EPHA5 | c.680G>A p.R227H | Missense Mutation (SNP) | VAF 124/212 reads (58%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as rs772693559, COSV56639156; called by muse, mutect2, varscan2
- EPHB2 | c.1958A>G p.K653R (on ENST00000400191 / NM_001309193.2; = p.K654R on NM_004442.7) | Missense Mutation (SNP) | VAF 82/364 reads (23%) | SIFT tolerated (0.07); PolyPhen probably damaging (1); catalogued as rs1007510252; called by muse, mutect2, varscan2
- ERBB3 | c.2036G>T p.R679L | Missense Mutation (SNP) | VAF 167/332 reads (50%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV57252242; called by muse, mutect2, varscan2
- ERC2 | c.769G>A p.E257K | Missense Mutation (SNP) | VAF 180/210 reads (86%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.974); catalogued as rs866429245, COSV55642982; called by muse, mutect2, varscan2
- FBN1 | c.1571C>T p.T524M | Missense Mutation (SNP) | VAF 23/354 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs370575495; ClinVar: uncertain significance; called by muse, mutect2
- GPR6 | c.668C>T p.A223V | Missense Mutation (SNP) | VAF 158/568 reads (28%) | SIFT deleterious (0.01); PolyPhen benign (0.166); catalogued as rs898785367, COSV51571702, COSV99254150; called by muse, varscan2
- IGHV3-48 | c.293T>C p.L98P | Missense Mutation (SNP) | VAF 38/628 reads (6%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.662); catalogued as rs1196983482; called by muse, mutect2
- ITPR3 | c.2321G>A p.R774H | Missense Mutation (SNP) | VAF 178/632 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs369403597; called by muse, mutect2, varscan2
- KCTD8 | c.1171C>T p.R391C | Missense Mutation (SNP) | VAF 244/392 reads (62%) | SIFT deleterious (0); PolyPhen probably damaging (0.927); catalogued as rs549391615, COSV63588118; called by muse, mutect2, varscan2
- KIRREL3 | c.683G>A p.R228H | Missense Mutation (SNP) | VAF 57/335 reads (17%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.977); catalogued as rs546310584, COSV73106273; called by muse, mutect2, varscan2
- KLHL42 | c.1313C>T p.S438L | Missense Mutation (SNP) | VAF 161/2980 reads (5%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.994); catalogued as rs759832133; called by muse, mutect2
- MYOC | c.729C>T p.T243= | Splice Region (SNP) | VAF 58/242 reads (24%) | catalogued as rs1014944863, COSV50675092, COSV50679823; called by muse, mutect2, varscan2
- PNPLA7 | c.3169G>A p.V1057M | Missense Mutation (SNP) | VAF 101/255 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs141633875; called by muse, mutect2, varscan2
- PRDM11 | c.1349G>A p.R450H (on ENST00000530656 / NM_001359633.1; = p.R416H on NM_001256695.1) | Missense Mutation (SNP) | VAF 46/294 reads (16%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.998); catalogued as rs755641215; called by muse, mutect2, varscan2
- PRR14L | c.100A>G p.R34G | Missense Mutation (SNP) | VAF 90/359 reads (25%) | SIFT deleterious (0.01); PolyPhen benign (0.009); catalogued as rs1332006583; called by muse, mutect2, varscan2
- RAB9B | c.82G>A p.V28I | Missense Mutation (SNP) | VAF 192/192 reads (100%) | SIFT tolerated (0.09); PolyPhen benign (0.241); catalogued as rs1321964920, COSV54588235; called by muse, mutect2, varscan2
- RPAP1 | c.2846G>A p.R949H | Missense Mutation (SNP) | VAF 98/322 reads (30%) | SIFT tolerated (0.05); PolyPhen benign (0.066); catalogued as rs764481480; called by muse, mutect2, varscan2
- SLC4A4 | c.2242G>A p.V748M (on ENST00000264485 / NM_001098484.3; = p.V704M on NM_003759.4) | Missense Mutation (SNP) | VAF 78/315 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.965); catalogued as rs760895286, COSV52614711; called by muse, mutect2, varscan2
- SORCS3 | c.1786G>A p.D596N | Missense Mutation (SNP) | VAF 116/209 reads (56%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.84); catalogued as rs142652556; called by muse, mutect2, varscan2
- SYNE1 | c.5783G>A p.G1928D (on ENST00000367255 / NM_182961.4; = p.G1935D on NM_033071.3) | Missense Mutation (SNP) | VAF 202/450 reads (45%) | SIFT deleterious (0.01); PolyPhen benign (0.145); catalogued as rs1241708653, COSV99569895; called by muse, varscan2
- SYTL5 | c.1917G>T p.W639C | Missense Mutation (SNP) | VAF 26/184 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV52905424; called by mutect2, varscan2
- TECTA | c.851G>A p.R284H | Missense Mutation (SNP) | VAF 49/277 reads (18%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.996); catalogued as rs886047837, COSV50690989; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- WDR27 | c.1412A>G p.N471S | Missense Mutation (SNP) | VAF 164/374 reads (44%) | SIFT tolerated (1); PolyPhen benign (0.012); catalogued as rs752264499; called by muse, mutect2, varscan2
- ZNF302 | c.734_735del p.R245Nfs*11 (on ENST00000627982; = p.R166Nfs*11 on NM_018443.3 and 3 other RefSeq transcripts) | Frame Shift Del (DEL) | VAF 38/166 reads (23%) | catalogued as rs763548605; called by pindel, varscan2
- APBB2 | c.406G>A p.E136K | Missense Mutation (SNP) | VAF 252/390 reads (65%) | SIFT tolerated (0.21); PolyPhen benign (0.323); called by muse, mutect2, varscan2
- ARAP2 | c.5022G>T p.K1674N | Missense Mutation (SNP) | VAF 145/240 reads (60%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); called by mutect2, varscan2
- ASH1L | c.6807dup p.Q2270Tfs*5 (on ENST00000368346 / NM_001366177.2; = p.Q2265Tfs*5 on NM_018489.3) | Frame Shift Ins (INS) | VAF 189/368 reads (51%) | called by mutect2, pindel, varscan2
- C5 | c.2T>A p.M1? | Translation Start Site (SNP) | VAF 116/204 reads (57%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); called by muse, mutect2, varscan2
- CCDC59 | c.498A>C p.K166N | Missense Mutation (SNP) | VAF 24/573 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2
- CGRRF1 | c.892T>G p.C298G | Missense Mutation (SNP) | VAF 166/389 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- CNTLN | c.2477C>G p.T826S | Missense Mutation (SNP) | VAF 81/392 reads (21%) | SIFT tolerated (0.25); PolyPhen possibly damaging (0.73); called by muse, mutect2, varscan2
- CNTN5 | c.601A>C p.T201P | Missense Mutation (SNP) | VAF 160/161 reads (99%) | SIFT tolerated (0.32); PolyPhen possibly damaging (0.725); called by muse, varscan2
- DYRK1A | c.2011T>C p.S671P | Missense Mutation (SNP) | VAF 309/312 reads (99%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.91); called by muse, mutect2, varscan2
- ELAPOR2 | c.925G>A p.V309M (on ENST00000450689 / NM_001142749.3; = p.V142M on NM_152748.4 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 126/239 reads (53%) | SIFT tolerated (0.19); PolyPhen possibly damaging (0.642); called by muse, mutect2, varscan2
- EMILIN1 | c.436C>T p.P146S | Missense Mutation (SNP) | VAF 42/678 reads (6%) | SIFT deleterious (0.03); PolyPhen benign (0.169); called by muse, mutect2
- F2RL3 | c.530C>G p.A177G | Missense Mutation (SNP) | VAF 64/535 reads (12%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.533); called by muse, mutect2, varscan2
- FBXO43 | c.1102G>C p.V368L | Missense Mutation (SNP) | VAF 57/273 reads (21%) | SIFT tolerated (0.24); PolyPhen benign (0.084); called by muse, mutect2, varscan2
- HAP1 | c.52G>C p.G18R | Missense Mutation (SNP) | VAF 37/1276 reads (3%) | SIFT tolerated, low confidence (0.1); PolyPhen benign (0.055); called by muse, mutect2
- HIF1A | c.194G>C p.S65T | Missense Mutation (SNP) | VAF 57/249 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.915); called by muse, mutect2, varscan2
- HIVEP1 | c.5834G>A p.C1945Y | Missense Mutation (SNP) | VAF 245/367 reads (67%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- HOOK2 | c.1081C>T p.Q361* | Nonsense Mutation (SNP) | VAF 266/304 reads (88%) | called by muse, varscan2
- IGHV6-1 | c.299A>T p.N100I | Missense Mutation (SNP) | VAF 159/337 reads (47%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- IGKV1D-16 | c.200A>C p.K67T | Missense Mutation (SNP) | VAF 28/504 reads (6%) | SIFT tolerated (0.07); PolyPhen benign (0.168); called by muse, mutect2
- KDM2B | c.3420G>C p.Q1140H | Missense Mutation (SNP) | VAF 10/279 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); called by muse, mutect2
- KIF5C | c.73C>T p.R25C | Missense Mutation (SNP) | VAF 92/394 reads (23%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.748); called by muse, mutect2, varscan2
- LRRC1 | c.504-1G>C p.X168_splice | Splice Site (SNP) | VAF 52/182 reads (29%) | called by muse, mutect2, varscan2
- MAGEB16 | c.755A>C p.K252T | Missense Mutation (SNP) | VAF 198/199 reads (99%) | SIFT deleterious (0.04); PolyPhen benign (0.439); called by mutect2, varscan2
- NANS | c.472G>A p.G158R | Missense Mutation (SNP) | VAF 63/304 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- NHSL1 | c.910A>G p.N304D | Missense Mutation (SNP) | VAF 82/494 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.957); called by muse, mutect2, varscan2
- OR10K2 | c.732C>A p.H244Q | Missense Mutation (SNP) | VAF 144/165 reads (87%) | SIFT deleterious (0); PolyPhen probably damaging (0.977); called by muse, mutect2, varscan2
- PDCD2L | c.695A>G p.N232S | Missense Mutation (SNP) | VAF 104/181 reads (57%) | SIFT tolerated (0.98); PolyPhen benign (0); called by muse, mutect2, varscan2
- PNLIPRP2 | c.1043C>T p.T348I | Missense Mutation (SNP) | VAF 32/199 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- PTPN21 | c.2101C>G p.L701V | Missense Mutation (SNP) | VAF 288/729 reads (40%) | SIFT deleterious, low confidence (0.05); PolyPhen probably damaging (0.985); called by muse, mutect2, varscan2
- SGCZ | c.31G>T p.E11* | Nonsense Mutation (SNP) | VAF 162/960 reads (17%) | called by muse, varscan2
- SGCZ | c.30G>T p.E10D | Missense Mutation (SNP) | VAF 165/972 reads (17%) | SIFT tolerated (0.07); PolyPhen benign (0.011); called by muse, varscan2
- SLCO4A1 | c.686T>A p.V229D | Missense Mutation (SNP) | VAF 113/820 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.943); called by mutect2, varscan2
- SMAP1 | c.445T>G p.L149V | Missense Mutation (SNP) | VAF 87/278 reads (31%) | SIFT tolerated (0.57); PolyPhen benign (0.017); called by muse, mutect2, varscan2
- STARD9 | c.5845T>A p.S1949T | Missense Mutation (SNP) | VAF 110/343 reads (32%) | SIFT tolerated (0.09); PolyPhen benign (0.341); called by muse, mutect2, varscan2
- SYNE1 | c.8921C>T p.A2974V (on ENST00000367255 / NM_182961.4; = p.A2981V on NM_033071.3) | Missense Mutation (SNP) | VAF 281/477 reads (59%) | SIFT tolerated (0.15); PolyPhen benign (0.035); called by muse, mutect2, varscan2
- TARS2 | c.1603T>A p.F535I | Missense Mutation (SNP) | VAF 302/475 reads (64%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- TCERG1L | c.181G>T p.V61L | Missense Mutation (SNP) | VAF 126/400 reads (32%) | SIFT tolerated, low confidence (0.98); PolyPhen benign (0); called by muse, mutect2, varscan2
- TMEM121B | c.37T>C p.S13P | Missense Mutation (SNP) | VAF 139/527 reads (26%) | SIFT tolerated, low confidence (0.08); PolyPhen benign (0); called by muse, mutect2, varscan2
- TPTE | c.1656A>C p.*552Yext*2 (on ENST00000618007 / NM_199261.4; = p.*534Yext*2 on NM_199259.4) | Nonstop Mutation (SNP) | VAF 22/280 reads (8%) | called by muse, mutect2
- TRHDE | c.290G>A p.R97Q | Missense Mutation (SNP) | VAF 480/1198 reads (40%) | SIFT tolerated (0.35); PolyPhen benign (0); called by muse, mutect2, varscan2
- TRPM5 | c.313A>G p.T105A | Missense Mutation (SNP) | VAF 16/288 reads (6%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.919); called by muse, mutect2
- USP5 | c.1753A>C p.K585Q | Missense Mutation (SNP) | VAF 168/254 reads (66%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.986); called by muse, mutect2, varscan2
- VEGFC | c.507G>C p.E169D | Missense Mutation (SNP) | VAF 165/253 reads (65%) | SIFT deleterious (0); PolyPhen probably damaging (0.985); called by muse, mutect2, varscan2
- VEGFD | c.256T>C p.S86P | Missense Mutation (SNP) | VAF 11/168 reads (7%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.71); called by muse, mutect2
- WNK2 | c.1084G>A p.E362K | Missense Mutation (SNP) | VAF 132/287 reads (46%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- ZNF527 | c.1453C>T p.L485F | Missense Mutation (SNP) | VAF 193/355 reads (54%) | SIFT deleterious (0); PolyPhen benign (0.44); called by muse, mutect2, varscan2
- ZNF675 | c.1669del p.I557Yfs*35 | Frame Shift Del (DEL) | VAF 87/329 reads (26%) | called by mutect2, pindel, varscan2
- ABCA1 | c.4722C>G p.L1574= | Silent (SNP) | VAF 135/371 reads (36%) | called by muse, mutect2
- APCS | c.453C>A p.V151= | Silent (SNP) | VAF 89/397 reads (22%) | called by muse, mutect2, varscan2
- CASKIN1 | c.3168C>T p.G1056= | Silent (SNP) | VAF 182/524 reads (35%) | catalogued as rs774444876; called by muse, mutect2, varscan2
- CDH15 | c.1392C>T p.T464= | Silent (SNP) | VAF 33/526 reads (6%) | catalogued as rs768449943; called by muse, mutect2
- CNP | c.525G>A p.K175= | Silent (SNP) | VAF 40/725 reads (6%) | called by muse, mutect2
- CNTNAP5 | c.516C>T p.Y172= | Silent (SNP) | VAF 60/242 reads (25%) | catalogued as rs368252422, COSV70484949; called by muse, mutect2, varscan2
- CPEB1 | c.64C>T p.L22= | Silent (SNP) | VAF 110/329 reads (33%) | called by muse, mutect2, varscan2
- CYLC1 | c.624G>A p.K208= | Silent (SNP) | VAF 39/255 reads (15%) | catalogued as rs1442443985; called by muse, mutect2, varscan2
- CYP4F2 | c.810C>A p.V270= | Silent (SNP) | VAF 42/298 reads (14%) | called by muse, mutect2, varscan2
- EDEM3 | c.2370T>C p.S790= | Silent (SNP) | VAF 90/224 reads (40%) | called by muse, mutect2, varscan2
- EME1 | c.1263C>G p.A421= | Silent (SNP) | VAF 34/479 reads (7%) | catalogued as rs367778832; called by muse, mutect2
- EPDR1 | c.60C>T p.G20= | Silent (SNP) | VAF 30/670 reads (4%) | called by muse, mutect2
- FCGR3B | c.129G>T p.V43= | Silent (SNP) | VAF 285/287 reads (99%) | called by muse, mutect2
- FGF23 | c.549C>T p.D183= | Silent (SNP) | VAF 212/626 reads (34%) | catalogued as rs369808475; called by muse, mutect2, varscan2
- FYCO1 | c.4149G>A p.E1383= | Silent (SNP) | VAF 266/321 reads (83%) | called by muse, mutect2, varscan2
- GPR180 | c.9G>A p.G3= | Silent (SNP) | VAF 288/296 reads (97%) | catalogued as rs961691083; called by muse, mutect2, varscan2
- GSDMD | c.868C>T p.L290= | Silent (SNP) | VAF 20/723 reads (3%) | called by muse, mutect2
- HOMER2 | c.66G>A p.K22= | Silent (SNP) | VAF 121/388 reads (31%) | catalogued as rs771821197; called by muse, mutect2, varscan2
- IGLV1-40 | c.225G>T p.R75= | Silent (SNP) | VAF 264/438 reads (60%) | called by muse, mutect2, varscan2
- ITIH5 | c.591C>T p.I197= | Silent (SNP) | VAF 226/473 reads (48%) | catalogued as rs369114884, COSV56904119, COSV56912641; called by muse, mutect2, varscan2
- KIF2B | c.93C>T p.Y31= | Silent (SNP) | VAF 207/461 reads (45%) | catalogued as rs775762338; called by muse, mutect2, varscan2
- KRTDAP | c.201C>T p.H67= | Silent (SNP) | VAF 137/272 reads (50%) | catalogued as rs766841840; called by muse, mutect2, varscan2
- MOB3C | c.639G>C p.R213= | Silent (SNP) | VAF 212/317 reads (67%) | catalogued as rs1295333067; called by muse, mutect2, varscan2
- MTCH1 | c.165G>A p.R55= | Silent (SNP) | VAF 329/991 reads (33%) | called by muse, mutect2, varscan2
- NCOR2 | c.7524G>A p.E2508= | Silent (SNP) | VAF 161/161 reads (100%) | called by muse, mutect2, varscan2
- NR5A1 | c.606C>T p.A202= | Silent (SNP) | VAF 365/726 reads (50%) | called by muse, mutect2, varscan2
- OR6C74 | c.424C>T p.L142= | Silent (SNP) | VAF 21/561 reads (4%) | catalogued as COSV59607568; called by muse, mutect2
- OXCT1 | c.486G>A p.G162= | Silent (SNP) | VAF 179/365 reads (49%) | called by muse, mutect2, varscan2
- PBXIP1 | c.1023G>T p.L341= | Silent (SNP) | VAF 252/1282 reads (20%) | called by muse, mutect2, varscan2
- PGR | c.1086G>A p.A362= | Silent (SNP) | VAF 290/292 reads (99%) | catalogued as rs142077957; called by muse, varscan2
- PLD5 | c.1605C>T p.N535= (on ENST00000442594; = p.N473= on NM_001195811.1 and 1 other RefSeq transcript) | Silent (SNP) | VAF 18/228 reads (8%) | catalogued as rs373263370, COSV100138693; called by muse, mutect2
- PRLHR | c.12G>A p.S4= | Silent (SNP) | VAF 118/202 reads (58%) | catalogued as rs867151973, COSV53304059; called by muse, mutect2, varscan2
- PXDNL | c.2295C>T p.R765= | Silent (SNP) | VAF 358/766 reads (47%) | catalogued as COSV100681376; called by muse, varscan2
- REELD1 | c.735T>G p.T245= | Silent (SNP) | VAF 209/323 reads (65%) | called by muse, mutect2, varscan2
- RSPH10B | c.1599C>T p.F533= | Silent (SNP) | VAF 43/136 reads (32%) | catalogued as rs771388883, COSV100521199; called by muse, mutect2, varscan2
- RSPH10B2 | c.1599C>T p.C533= | Silent (SNP) | VAF 31/195 reads (16%) | catalogued as rs748374279; called by muse, mutect2, varscan2
- STYXL2 | c.3018G>C p.R1006= | Silent (SNP) | VAF 29/481 reads (6%) | called by muse, mutect2
- USH2A | c.7017A>G p.T2339= | Silent (SNP) | VAF 190/373 reads (51%) | catalogued as rs1426861450, COSV100233083; called by muse, mutect2, varscan2
- VPS13B | c.10275G>A p.P3425= | Silent (SNP) | VAF 28/494 reads (6%) | catalogued as rs151315104; called by muse, mutect2
- BIRC7 | c.450-99C>T | Intron (SNP) | VAF 170/1259 reads (14%) | catalogued as rs530112822; called by muse, mutect2, varscan2
- C2CD4A | c.*1779A>C | 3'UTR (SNP) | VAF 24/274 reads (9%) | called by muse, mutect2
- CHEK1 | chr11:125625879 G>A | 5'Flank (SNP) | VAF 37/464 reads (8%) | catalogued as rs946157626; called by muse, mutect2
- FAM21FP | n.179C>G | RNA (SNP) | VAF 209/387 reads (54%) | called by muse, mutect2, varscan2
- NMNAT2 | c.86-10900G>A | Intron (SNP) | VAF 26/376 reads (7%) | called by muse, mutect2
- PITPNB | c.*53T>A | 3'UTR (SNP) | VAF 134/364 reads (37%) | called by muse, mutect2, varscan2
- PRR30 | c.*3C>T | 3'UTR (SNP) | VAF 172/542 reads (32%) | catalogued as COSV99574229; called by muse, mutect2
- RNF213 | c.-1C>A | 5'UTR (SNP) | VAF 159/352 reads (45%) | called by muse, mutect2, varscan2
